Somatic mutation profile of tumor specimen TCGA-CN-4725-01A (aliquot TCGA-CN-4725-01A-01D-1434-08) from TCGA case TCGA-CN-4725, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 60.7 years (22,171 days).
Specimen TCGA-CN-4725-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a9bbd2e-f2f9-44c3-8bfa-6995c07cf8d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4725-10A (Blood Derived Normal), aliquot TCGA-CN-4725-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a52094d-79a1-404b-9137-c444d365b9f4

The open-access MAF lists 60 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 15, Frame Shift Del 4, Nonsense Mutation 2, Frame Shift Ins 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYNC2H1 | c.739C>T p.R247* | Nonsense Mutation (SNP) | VAF 27/259 reads (10%) | catalogued as rs561778796, COSV100517144; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by mutect2, varscan2
- ADAMTS9 | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as rs554151476, COSV99898452; called by muse, mutect2, varscan2
- APBA1 | c.2267G>C p.R756P | Missense Mutation (SNP) | VAF 35/295 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99595256; called by muse, mutect2, varscan2
- CCDC190 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 157/792 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs773281055, COSV100905797, COSV63363126, COSV63363346; called by muse, mutect2, varscan2
- CDH10 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.139); catalogued as COSV100049659; called by muse, mutect2
- CLEC16A | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as rs746938479, COSV101277782; called by muse, mutect2, varscan2
- CNGA1 | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 145/345 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV62056074; called by muse, mutect2, varscan2
- DOK1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV99283887; called by muse, mutect2, varscan2
- EVX2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100420508; called by muse, mutect2, varscan2
- GPR26 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs777801682, COSV52933064; called by muse, mutect2, varscan2
- GPR37L1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1437696930, COSV66161936, COSV66162309; called by muse, mutect2, varscan2
- KLHL25 | c.1556C>T p.T519M | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.892); catalogued as rs774760536, COSV61996760; called by muse, mutect2, varscan2
- LRCH2 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.761); catalogued as COSV57746102; called by muse, mutect2, varscan2
- MARCO | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 126/399 reads (32%) | catalogued as COSV100503096, COSV59051937; called by muse, mutect2, varscan2
- MED12 | c.5198G>A p.R1733Q | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs754537871, COSV99048835; called by muse, mutect2, varscan2
- OR2J2 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 225/505 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV101013254; called by muse, mutect2, varscan2
- PALB2 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as rs764599493, COSV99847903; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCLO | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); catalogued as rs1329684450, COSV100426378; called by muse, mutect2, varscan2
- RABGGTB | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99590360; called by muse, mutect2, varscan2
- RING1 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100761704; called by muse, mutect2, varscan2
- RTF1 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101047469; called by muse, mutect2, varscan2
- SEC16A | c.2974G>A p.G992R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs758060948, COSV99255663, COSV99258497; called by muse, mutect2, varscan2
- SNRNP200 | c.5345C>T p.S1782L | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV100106903; called by muse, mutect2, varscan2
- ST3GAL1 | c.849+1G>T p.X283_splice | Splice Site (SNP) | VAF 110/288 reads (38%) | catalogued as COSV100171719; called by muse, mutect2, varscan2
- STK32B | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371890370; called by muse, mutect2, varscan2
- STYXL1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs576061630, COSV50390010; called by muse, mutect2, varscan2
- SUPT6H | c.3386A>C p.E1129A | Missense Mutation (SNP) | VAF 137/286 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100111986; called by muse, mutect2, varscan2
- THAP10 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99997684; called by muse, mutect2, varscan2
- TMEM198 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs758187620, COSV99523466; called by muse, mutect2, varscan2
- TNN | c.2239G>A p.D747N | Missense Mutation (SNP) | VAF 90/249 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99510831; called by muse, mutect2, varscan2
- TNRC6A | c.5694T>A p.N1898K | Missense Mutation (SNP) | VAF 157/476 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as COSV100169290; called by muse, mutect2, varscan2
- TRGV5 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs762527800; called by muse, mutect2, varscan2
- TUBB6 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.577); catalogued as rs746302836, COSV99301405; called by muse, mutect2, varscan2
- VCAN | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.02); catalogued as COSV99424298; called by muse, mutect2, varscan2
- ZFP91 | c.1229G>T p.R410L | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100284274; called by muse, mutect2, varscan2
- ZG16B | c.125C>T p.T42M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1241909776, COSV66525642; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1459T>G p.S487A | Missense Mutation (SNP) | VAF 121/362 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV100459967; called by muse, mutect2, varscan2
- ZNF791 | c.1708del p.H570Ifs*2 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as rs1392470422; called by mutect2, pindel, varscan2
- ALMS1 | c.9236del p.M3079Rfs*24 | Frame Shift Del (DEL) | VAF 55/199 reads (28%) | called by mutect2, pindel, varscan2
- KRT5 | c.209dup p.S71Lfs*9 | Frame Shift Ins (INS) | VAF 77/169 reads (46%) | called by mutect2, pindel, varscan2
- RNGTT | c.704del p.G235Vfs*7 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2, pindel
- SPOP | c.44_47dup p.P17Wfs*5 | Frame Shift Ins (INS) | VAF 25/273 reads (9%) | called by mutect2, pindel
- TBC1D10A | c.1413_1428del p.K472Rfs*22 | Frame Shift Del (DEL) | VAF 47/316 reads (15%) | called by mutect2, pindel, varscan2
- ARMH4 | c.273G>A p.S91= | Silent (SNP) | VAF 84/233 reads (36%) | catalogued as rs1161059001, COSV50762857, COSV50774834; called by muse, mutect2, varscan2
- F5 | c.417C>T p.D139= | Silent (SNP) | VAF 89/254 reads (35%) | catalogued as rs749722664, COSV63120009; ClinVar: likely benign; called by muse, mutect2, varscan2
- H1-4 | c.552G>T p.A184= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56804006, COSV99175188; called by muse, mutect2, varscan2
- KIAA1522 | c.996C>T p.R332= (on ENST00000373480 / NM_001198972.2; = p.R391= on NM_020888.3) | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as COSV99614031; called by muse, mutect2, varscan2
- LAMA5 | c.5325C>A p.R1775= | Silent (SNP) | VAF 54/110 reads (49%) | catalogued as COSV99437431; called by muse, mutect2, varscan2
- LTBP2 | c.5316C>T p.C1772= | Silent (SNP) | VAF 110/300 reads (37%) | catalogued as rs781130604, COSV99999475; called by muse, mutect2, varscan2
- MAN1B1 | c.1026C>G p.A342= | Silent (SNP) | VAF 61/194 reads (31%) | catalogued as COSV100857978; called by muse, mutect2, varscan2
- MED23 | c.2790G>A p.E930= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV100644676; called by muse, mutect2, varscan2
- MMP9 | c.1200G>A p.A400= | Silent (SNP) | VAF 95/197 reads (48%) | catalogued as rs201927079, COSV63434310; called by muse, mutect2, varscan2
- PXDN | c.2979C>T p.R993= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs933114521, COSV99411928; called by muse, mutect2, varscan2
- SCYL1 | c.969C>T p.F323= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as rs555597732, COSV54215737; called by muse, mutect2, varscan2
- SLC28A1 | c.600C>T p.C200= | Silent (SNP) | VAF 92/157 reads (59%) | catalogued as rs771748099, COSV99722339; called by muse, mutect2, varscan2
- SOX11 | c.1029G>A p.S343= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58983625; called by muse, mutect2
- TTF1 | c.1596C>T p.V532= | Silent (SNP) | VAF 37/71 reads (52%) | catalogued as rs747116451, COSV57503433; called by muse, mutect2, varscan2
- ZBTB46 | c.744C>T p.D248= | Silent (SNP) | VAF 62/176 reads (35%) | catalogued as rs202040562, COSV99828635; called by muse, mutect2, varscan2
- PRB3 | c.604+9G>T | Intron (SNP) | VAF 184/1352 reads (14%) | catalogued as COSV99685416; called by muse, varscan2
